Surgical pathology report (de-identified scan), TCGA case TCGA-EC-A24G, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Asterand, specimen TCGA-EC-A24G-01A (Primary Tumor).

1CD-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: Endometrium C54.1

fw

4/26/11

UTERUS TISSUE CHECKLIST

Specimen type: Hysterectomy, bilateral salpingo-oophorectomy
Tumor site: Endometrium
Tumor size: 6 x 0 x 7 cm
Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Tumor extent: Invasion of cervix
Lymph nodes: 0/15 positive for metastasis (Pelvic fatty tissue 0/15)
Lymphatic invasion: Not specified
Venous invasion: Absent
Extent of myometrial invasion: Not specified
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: Grade 3 endometrioid adenocarcinoma

Criteria	Yes
Case (circle):	
Reliability	

Source: NCI Genomic Data Commons file 9a95bb75-c0f9-4e37-930a-c1f2c244ef50 (TCGA-EC-A24G.5DE142C5-7A0D-4C5E-8EF6-2809B10378C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).